Somatic mutation profile of tumor specimen 0DFJMW from CCDI case PBBSFM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.0 years (4,758 days).
Specimen 0DFJMW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68a73489-ba59-4858-b47d-72a12c8a4a33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFJIZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a859e85e-6b8a-40e5-8e41-50ec5cb2484e

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC5AC | c.7259C>T p.T2420I | Missense Mutation (SNP) | VAF 20/725 reads (3%) | SIFT deleterious (0.03); catalogued as rs1290902777; called by muse, mutect2
- ARHGDIG | c.73G>T p.V25F | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- PPP1R9A | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 8/219 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- PTGFRN | c.1122C>G p.H374Q | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLCO2B1 | c.134T>C p.F45S | Missense Mutation (SNP) | VAF 16/472 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- THOC2 | c.1216G>T p.G406C | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- KRTAP4-5 | c.159C>A p.P53= | Silent (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- SAFB2 | c.432T>G p.A144= | Silent (SNP) | VAF 10/268 reads (4%) | called by muse, mutect2
- CD40 | c.52-44C>T | Intron (SNP) | VAF 43/171 reads (25%) | catalogued as rs750963838; called by muse, mutect2, varscan2
- MUC19 | chr12:40545354 G>A | 3'Flank (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
